Somatic mutation profile of tumor specimen TCGA-56-1622-01A (aliquot TCGA-56-1622-01A-01D-1521-08) from TCGA case TCGA-56-1622, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 58.5 years (21,371 days).
Specimen TCGA-56-1622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 263eb0d8-8aca-4e33-9112-bd54b38b1f16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-1622-11A (Solid Tissue Normal), aliquot TCGA-56-1622-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d11a778-fd7f-4df7-8392-278770ae2ddf

The open-access MAF lists 248 somatic variants for this specimen: 179 protein-altering or splice-affecting, 63 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 63, Nonsense Mutation 7, Splice Site 7, Frame Shift Del 5, Frame Shift Ins 3, 5'Flank 2, Intron 2, 5'UTR 1, Nonstop Mutation 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 29/38 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1856T>C p.L619P | Missense Mutation (SNP) | VAF 111/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55746357; called by muse, mutect2, varscan2
- ABCA1 | c.5057A>T p.H1686L | Missense Mutation (SNP) | VAF 94/108 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV66064169; called by muse, mutect2, varscan2
- ADARB2 | c.1942C>A p.L648M | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as rs996734955, COSV67181919; called by muse, mutect2, varscan2
- AHI1 | c.44G>C p.R15P | Missense Mutation (SNP) | VAF 115/246 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV55623563, COSV55626363; called by muse, mutect2, varscan2
- APPL2 | c.1496T>G p.L499W | Missense Mutation (SNP) | VAF 68/75 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51588534; called by muse, mutect2, varscan2
- ARFRP1 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 133/373 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV53926570, COSV53926863; called by muse, mutect2, varscan2
- ARHGEF10L | c.2955G>A p.W985* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as COSV51428797; called by muse, mutect2, varscan2
- ARHGEF2 | c.2209-1G>A p.X737_splice (on ENST00000361247 / NM_001162383.2; = p.X709_splice on NM_004723.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 117/225 reads (52%) | catalogued as COSV58107135, COSV58114043; called by muse, mutect2, varscan2
- BEST1 | c.1457C>A p.P486Q | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV56444675, COSV99861428; called by muse, mutect2, varscan2
- BTNL2 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs745983253, COSV66630245; called by muse, mutect2, varscan2
- C1GALT1C1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 91/102 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs773375422, COSV58973778; called by muse, mutect2, varscan2
- C6orf136 | c.754G>A p.E252K (on ENST00000376473 / NM_001109938.3; = p.E118K on NM_145029.4) | Missense Mutation (SNP) | VAF 195/379 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs776450954, COSV53312391; called by muse, mutect2, varscan2
- CAPSL | c.136A>G p.R46G | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV68437329; called by muse, mutect2, varscan2
- CCDC178 | c.2338A>G p.I780V (on ENST00000383096 / NM_001105528.3; = p.I742V on NM_198995.3) | Missense Mutation (SNP) | VAF 71/83 reads (86%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV55761855; called by muse, mutect2, varscan2
- CCDC38 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 77/87 reads (89%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs200003296; called by muse, mutect2, varscan2
- CD207 | c.667T>C p.C223R | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69651747; called by muse, mutect2, varscan2
- CD226 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 79/98 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV54610390; called by muse, mutect2, varscan2
- CDH11 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51752888, COSV51764246; called by muse, mutect2, varscan2
- CDH18 | c.1637C>G p.T546R | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56904744; called by muse, mutect2, varscan2
- CDH20 | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 91/116 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV53004135, COSV53005406; called by muse, mutect2, varscan2
- CDH8 | c.1774T>A p.L592M | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54851192; called by muse, mutect2, varscan2
- CHRNA4 | c.1537C>A p.R513S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV64718599; called by muse, mutect2, varscan2
- CMBL | c.83A>G p.E28G | Missense Mutation (SNP) | VAF 174/596 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56982931; called by muse, mutect2, varscan2
- CNPY1 | c.128G>T p.R43I | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as rs1305203139, COSV58786675; called by muse, mutect2, varscan2
- COL3A1 | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58582805; called by muse, mutect2, varscan2
- COL4A1 | c.3950-1G>C p.X1317_splice | Splice Site (SNP) | VAF 74/88 reads (84%) | catalogued as COSV65422134; called by muse, varscan2
- CORO7 | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 47/55 reads (85%) | catalogued as COSV52028354; called by muse, mutect2, varscan2
- CYP3A43 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs771535128, COSV55935203; called by muse, mutect2, varscan2
- DCDC1 | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs371778122; called by muse, mutect2
- DCTN1 | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV62619747; called by muse, mutect2, varscan2
- DHFR2 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 53/66 reads (80%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV58934172; called by muse, mutect2, varscan2
- DMXL2 | c.1678A>G p.K560E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV51841505, COSV99196325; called by muse, mutect2, varscan2
- DNAH17 | c.11774C>A p.A3925D | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67750370; called by muse, mutect2, varscan2
- DPH2 | c.13T>C p.F5L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV52542667; called by muse, mutect2, varscan2
- DPYD | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV60075541; called by muse, mutect2, varscan2
- DPYS | c.1462G>T p.V488L | Missense Mutation (SNP) | VAF 181/197 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60906729; called by muse, mutect2, varscan2
- EML1 | c.1171G>T p.G391* | Nonsense Mutation (SNP) | VAF 106/248 reads (43%) | catalogued as COSV51742077; called by muse, mutect2, varscan2
- EP300 | c.4193T>C p.L1398P | Missense Mutation (SNP) | VAF 148/371 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54327567; called by muse, mutect2, varscan2
- EPS8 | c.365A>T p.K122M | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55528114; called by muse, mutect2, varscan2
- FAM135B | c.1804C>A p.Q602K | Missense Mutation (SNP) | VAF 492/536 reads (92%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52708219; called by mutect2, varscan2
- FAM135B | c.1803C>A p.H601Q | Missense Mutation (SNP) | VAF 512/554 reads (92%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV52708236; called by mutect2, varscan2
- FAM135B | c.1624G>T p.G542C | Missense Mutation (SNP) | VAF 263/275 reads (96%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.817); catalogued as COSV52708258, COSV52714058; called by muse, mutect2, varscan2
- FLG | c.3945C>G p.D1315E | Missense Mutation (SNP) | VAF 98/333 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.191); catalogued as rs752779456, COSV64237598; called by muse, mutect2, varscan2
- FLG | c.25T>G p.F9V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64237605; called by muse, mutect2, varscan2
- FOLH1 | c.1498A>G p.K500E | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV57046281; called by muse, mutect2, varscan2
- FOXRED1 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55005419; called by muse, mutect2, varscan2
- FRMPD2 | c.3083G>C p.R1028T | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV59715692; called by muse, mutect2
- FRY | c.4240C>G p.L1414V | Missense Mutation (SNP) | VAF 68/82 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV66565982; called by muse, mutect2, varscan2
- GALNT17 | c.1140G>C p.E380D | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV61149750, COSV61155864; called by muse, mutect2, varscan2
- GARNL3 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 153/180 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV59224077, COSV59229221; called by muse, mutect2, varscan2
- GBP6 | c.670A>T p.I224F | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65010826; called by muse, mutect2, varscan2
- GLS | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.732); catalogued as COSV57840260; called by muse, mutect2
- GLUD1 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 77/92 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1340381250, COSV53277594; called by muse, mutect2, varscan2
- GPM6A | c.71dup p.I25Hfs*25 | Frame Shift Ins (INS) | VAF 53/110 reads (48%) | catalogued as rs1216366348; called by mutect2, pindel, varscan2
- GPRC5C | c.1409C>T p.P470L (on ENST00000652232; = p.P425L on NM_018653.4) | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs757207937, COSV61235555; called by muse, mutect2, varscan2
- H1-2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.267); catalogued as rs547650580, COSV59189838, COSV59191057; called by muse, mutect2, varscan2
- HAT1 | c.458del p.G153Efs*14 | Frame Shift Del (DEL) | VAF 40/84 reads (48%) | catalogued as COSV51362955; called by mutect2, varscan2
- HERC2 | c.6650T>A p.L2217Q | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV55310384; called by muse, mutect2, varscan2
- HLX | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65044383; called by muse, mutect2, varscan2
- IL31 | c.73C>A p.H25N | Missense Mutation (SNP) | VAF 87/107 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV65476094; called by muse, mutect2, varscan2
- ITGA11 | c.2903A>G p.Y968C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs753174019, COSV59875303; called by muse, mutect2, varscan2
- ITIH6 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV54486969, COSV99513798; called by muse, mutect2, varscan2
- KANSL1 | c.2834+1G>C p.X945_splice (on ENST00000574590 / NM_001193465.2; = p.X946_splice on NM_015443.4) | Splice Site (SNP) | VAF 6/12 reads (50%) | catalogued as COSV52237583; called by muse, varscan2
- KCNH8 | c.1604G>C p.R535P | Missense Mutation (SNP) | VAF 143/173 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60457598, COSV60477558; called by muse, mutect2, varscan2
- KCNIP4 | c.273C>G p.Y91* | Nonsense Mutation (SNP) | VAF 128/195 reads (66%) | catalogued as COSV62846039; called by muse, mutect2, varscan2
- KCNJ15 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs768675308, COSV60810326; called by muse, mutect2
- KLHL3 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.432); catalogued as rs1394919522, COSV59051170; called by muse, mutect2, varscan2
- KMT2C | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 44/618 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100074418, COSV51341509; called by muse, mutect2
- KREMEN1 | c.1357A>G p.I453V (on ENST00000407188; = p.I455V on NM_032045.5) | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.145); catalogued as rs761023660, COSV59911667; called by muse, mutect2, varscan2
- LCP1 | c.815G>C p.R272T | Missense Mutation (SNP) | VAF 99/117 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59939721; called by muse, mutect2, varscan2
- LDB2 | c.904G>T p.V302L | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58763449; called by muse, mutect2, varscan2
- LDHAL6A | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 293/379 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs762981632, COSV52648724; called by muse, mutect2, varscan2
- LIPI | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60708731; called by muse, mutect2, varscan2
- LMBRD2 | c.1583G>C p.G528A | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV56948846; called by muse, mutect2, varscan2
- LRBA | c.6363G>T p.K2121N | Missense Mutation (SNP) | VAF 169/463 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV58260966; called by muse, mutect2, varscan2
- LRRK2 | c.7124T>C p.V2375A | Missense Mutation (SNP) | VAF 93/106 reads (88%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.524); catalogued as rs1192524761, COSV54145521; called by muse, mutect2, varscan2
- MAP3K13 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 44/631 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as rs779365471, COSV53984208; called by muse, mutect2
- MAP3K13 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1283305765, COSV53984221; called by muse, mutect2
- MME | c.56A>T p.K19M | Missense Mutation (SNP) | VAF 155/185 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV64706181; called by muse, mutect2, varscan2
- MMP9 | c.1143C>A p.S381R | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV63433808, COSV63434510; called by muse, mutect2, varscan2
- MPP4 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59629356; called by muse, mutect2, varscan2
- MRAP | c.107-2A>G p.X36_splice | Splice Site (SNP) | VAF 91/156 reads (58%) | catalogued as COSV57936460; called by muse, mutect2, varscan2
- MROH2B | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV68181657, COSV68183436; called by muse, mutect2, varscan2
- MUC16 | c.25937C>A p.P8646H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV67448453, COSV67491582; called by muse, mutect2, varscan2
- MYEF2 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as COSV51046184; called by muse, mutect2, varscan2
- MYH13 | c.4618G>A p.E1540K | Missense Mutation (SNP) | VAF 66/79 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52821953; called by muse, mutect2, varscan2
- MYH2 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 68/92 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV55432587, COSV55437494; called by muse, mutect2, varscan2
- NBEA | c.2198A>C p.H733P | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59763551; called by muse, mutect2, varscan2
- NDUFAF6 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV54407339; called by muse, mutect2, varscan2
- NHS | c.3323C>T p.P1108L | Missense Mutation (SNP) | VAF 129/147 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs779002657, COSV66271970; called by muse, mutect2, varscan2
- NID1 | c.2923G>T p.V975F | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV51615679, COSV51620573; called by muse, mutect2, varscan2
- NIPSNAP3B | c.743A>T p.*248Lext*18 | Nonstop Mutation (SNP) | VAF 59/75 reads (79%) | catalogued as COSV66106407; called by muse, mutect2, varscan2
- NTSR1 | c.916+1G>C p.X306_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as rs764083183, COSV65138117, COSV65138272; called by muse, mutect2, varscan2
- OR2C3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63574532; called by muse, mutect2, varscan2
- OR2L3 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 110/237 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV63454567; called by muse, varscan2
- OR2T2 | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100737806; called by mutect2, varscan2
- OR4F6 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV61026377; called by muse, mutect2, varscan2
- OR6F1 | c.646G>T p.V216F | Missense Mutation (SNP) | VAF 92/161 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.301); catalogued as COSV57467020; called by muse, mutect2, varscan2
- OR8K5 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV57888006; called by muse, varscan2
- OR9Q2 | c.941C>A p.P314H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV61111473; called by muse, mutect2, varscan2
- OVCH1 | c.214T>C p.C72R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753299595, COSV55476301; called by muse, mutect2, varscan2
- PAPPA2 | c.4653C>G p.I1551M | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV62791724; called by muse, mutect2, varscan2
- PARD3B | c.2188T>A p.S730T (on ENST00000406610 / NM_001302769.2; = p.S668T on NM_152526.6) | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV62504145; called by muse, mutect2, varscan2
- PCDH11X | c.3563G>T p.R1188L | Missense Mutation (SNP) | VAF 129/152 reads (85%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs746951282, COSV53446521, COSV53467425; called by muse, mutect2, varscan2
- PCDHB10 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.718); catalogued as COSV53375930, COSV53384180; called by muse, mutect2, varscan2
- PCDHB2 | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.51); catalogued as COSV50564750; called by muse, mutect2, varscan2
- PCLO | c.14365G>A p.V4789M | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61616573, COSV61618641; called by muse, mutect2, varscan2
- PDE5A | c.1255A>G p.M419V | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.222); catalogued as COSV53345870; called by muse, mutect2
- PDILT | c.1346C>A p.A449E | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56699892; called by muse, mutect2, varscan2
- PKD1 | c.9677A>C p.N3226T | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.51); PolyPhen benign (0.277); catalogued as COSV51911578; called by muse, mutect2, varscan2
- PPA2 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); catalogued as rs1293383364, COSV58993637; called by muse, mutect2, varscan2
- PPP1R9B | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV57540818; called by muse, mutect2
- PRRC2C | c.7236G>T p.L2412F (on ENST00000367742; = p.L2410F on NM_015172.4) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV58901844; called by muse, mutect2, varscan2
- PRRC2C | c.7237G>T p.A2413S (on ENST00000367742; = p.A2411S on NM_015172.4) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.656); catalogued as rs750937319, COSV58901853; called by muse, mutect2, varscan2
- PTPN4 | c.2520G>T p.K840N | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV55298065; called by muse, mutect2, varscan2
- RANBP2 | c.9015G>T p.W3005C | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51697209; called by muse, mutect2, varscan2
- RASAL2 | c.3325C>T p.R1109W | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768397267, COSV62710456; called by muse, mutect2, varscan2
- RB1 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759079385, COSV57297764; ClinVar: likely benign; called by mutect2, varscan2
- REG3A | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100532652, COSV59408429; called by muse, mutect2, varscan2
- ROPN1L | c.378G>C p.W126C | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56873078, COSV56874992, COSV99928511; called by muse, mutect2, varscan2
- RPTN | c.363C>A p.H121Q | Missense Mutation (SNP) | VAF 107/345 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV60166463; called by muse, mutect2, varscan2
- RYR1 | c.1141G>T p.G381C | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62090644; called by muse, mutect2, varscan2
- RYR2 | c.5189C>T p.T1730M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs745569662, COSV63665961, COSV63668687; called by muse, mutect2, varscan2
- SAP30BP | c.815T>G p.L272R | Missense Mutation (SNP) | VAF 116/345 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV53126906; called by muse, mutect2, varscan2
- SCN1A | c.3657G>T p.W1219C (on ENST00000303395 / NM_001202435.3; = p.W1208C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM113317, COSV57661967; called by muse, mutect2, varscan2
- SCN1A | c.3656G>T p.W1219L (on ENST00000303395 / NM_001202435.3; = p.W1208L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as CM096102, COSV57661985, COSV57677893; called by muse, mutect2, varscan2
- SCRN1 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 110/132 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV54128706, COSV54128932; called by muse, mutect2, varscan2
- SERPINA5 | c.322C>G p.H108D | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61573642; called by muse, mutect2, varscan2
- SHANK3 | c.4363C>A p.R1455S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.842); catalogued as rs762975306, COSV53184133; called by muse, mutect2, varscan2
- SIM1 | c.861G>C p.K287N | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53489403, COSV99491906; called by muse, mutect2, varscan2
- SIM2 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 138/162 reads (85%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV51766454; called by muse, mutect2, varscan2
- SLITRK2 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 101/107 reads (94%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as COSV59423450; called by muse, mutect2, varscan2
- SMYD2 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV65290423, COSV65291973; called by muse, mutect2, varscan2
- SP4 | c.397G>C p.G133R | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT tolerated (0.59); PolyPhen benign (0.059); catalogued as COSV56021016; called by muse, mutect2, varscan2
- SPRY3 | c.293G>T p.R98M | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV57142028; called by muse, mutect2, varscan2
- SPTAN1 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63985673; called by muse, mutect2, varscan2
- SRGAP2 | c.3020T>C p.F1007S (on ENST00000624873 / NM_001170637.4; = p.F1008S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.065); catalogued as COSV55333880; called by muse, mutect2, varscan2
- STARD8 | c.1356C>A p.D452E | Missense Mutation (SNP) | VAF 49/50 reads (98%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV52922510; called by muse, mutect2, varscan2
- SYNGR4 | c.366C>A p.C122* | Nonsense Mutation (SNP) | VAF 98/190 reads (52%) | catalogued as COSV61225124; called by muse, mutect2, varscan2
- TEX13B | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 129/143 reads (90%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV57202208; called by muse, mutect2, varscan2
- TIMD4 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 77/99 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs747982212, COSV50854095; called by muse, mutect2, varscan2
- TJP1 | c.4680A>T p.K1560N | Missense Mutation (SNP) | VAF 186/227 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); catalogued as COSV62039827; called by muse, mutect2, varscan2
- TMX4 | c.410A>T p.E137V | Missense Mutation (SNP) | VAF 71/113 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55679862; called by muse, mutect2, varscan2
- TRIM49 | c.1142G>T p.G381V | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as COSV61670378; called by muse, mutect2, varscan2
- TRIM51 | c.539G>T p.R180I | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV55264248; called by muse, mutect2, varscan2
- TRPS1 | c.413A>T p.D138V (on ENST00000220888 / NM_001330599.2; = p.D151V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV55228430; called by muse, mutect2, varscan2
- TRPS1 | c.412G>T p.D138Y (on ENST00000220888 / NM_001330599.2; = p.D151Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV55228445; called by muse, mutect2, varscan2
- TTN | c.54728T>A p.L18243Q (on ENST00000591111; = p.L10819Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | PolyPhen probably damaging (0.999); catalogued as COSV59910430; called by muse, mutect2, varscan2
- UNC13B | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); catalogued as COSV65931627; called by muse, mutect2, varscan2
- UNC13C | c.6228G>T p.Q2076H | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52847320; called by muse, mutect2, varscan2
- URB2 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as COSV50981877; called by muse, mutect2, varscan2
- USH2A | c.9148del p.V3050Sfs*8 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | catalogued as COSV100235267; called by mutect2, pindel, varscan2
- USP3 | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs1306212576, COSV51426403; called by muse, mutect2, varscan2
- UTP11 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65951072; called by muse, mutect2, varscan2
- VAV1 | c.2446G>C p.G816R | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100409074, COSV58379493, COSV58386932; called by muse, mutect2, varscan2
- VPS16 | c.1379G>C p.R460P | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100988418, COSV66792545; called by muse, mutect2, varscan2
- WDR31 | c.780G>C p.T260= (on ENST00000374193 / NM_001006615.3; = p.T259= on NM_145241.5) | Splice Region (SNP) | VAF 86/105 reads (82%) | catalogued as rs148709910, COSV100516581, COSV59145447; called by muse, mutect2, varscan2
- WIF1 | c.634+1G>A p.X212_splice | Splice Site (SNP) | VAF 66/124 reads (53%) | catalogued as COSV54129952; called by muse, mutect2, varscan2
- ZFP57 | c.1380G>T p.R460S | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV65305729; called by muse, mutect2, varscan2
- ZNF142 | c.4477G>A p.A1493T (on ENST00000411696 / NM_001379660.1; = p.A1293T on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV68743054; called by muse, mutect2, varscan2
- ZNF234 | c.997A>G p.I333V | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as rs1384916061, COSV70602900; called by muse, mutect2, varscan2
- ZNF425 | c.1723A>G p.M575V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65200671; called by muse, mutect2, varscan2
- ZNF479 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 30/52 reads (58%) | catalogued as COSV58636354; called by muse, mutect2, varscan2
- ZNF625 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63241297; called by muse, mutect2, varscan2
- ZNF721 | c.2659G>A p.G887S (on ENST00000338977; = p.G899S on NM_133474.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV59089764; called by muse, mutect2, varscan2
- ZNF804B | c.3507G>T p.M1169I | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV60818170; called by muse, mutect2, varscan2
- ZNF804B | c.3508C>T p.Q1170* | Nonsense Mutation (SNP) | VAF 38/107 reads (36%) | catalogued as COSV60818177; called by muse, mutect2, varscan2
- CATSPERD | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CLASP2 | c.2072-6_2076del p.X691_splice | Splice Site (DEL) | VAF 30/51 reads (59%) | called by mutect2, pindel, varscan2
- CNTNAP4 | c.45A>T p.L15F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DST | c.10053G>T p.L3351F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FOXL2 | c.187_200del p.I63Pfs*28 | Frame Shift Del (DEL) | VAF 44/64 reads (69%) | called by mutect2, pindel, varscan2
- OR2T35 | c.457T>A p.S153T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by mutect2, varscan2
- PRMT7 | c.1508_1523del p.H503Pfs*3 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | called by mutect2, pindel, varscan2
- SYNRG | c.1612A>C p.K538Q | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- USP24 | c.2695dup p.M899Nfs*19 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- UTP18 | c.1628dup p.K544Qfs*6 | Frame Shift Ins (INS) | VAF 68/118 reads (58%) | called by mutect2, varscan2
- ZNF707 | c.74_75del p.L25Rfs*44 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | called by mutect2, pindel, varscan2
- ABCA13 | c.1566C>A p.S522= | Silent (SNP) | VAF 43/49 reads (88%) | catalogued as COSV70026103; called by muse, mutect2, varscan2
- ADAM2 | c.1053T>C p.F351= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV55859348; called by muse, mutect2, varscan2
- ADGRA3 | c.3513C>T p.H1171= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV51560589; called by muse, mutect2, varscan2
- ANAPC1 | c.3813A>G p.E1271= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as COSV100595114; called by mutect2, varscan2
- ANKMY1 | c.522G>T p.S174= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV56030750; called by muse, mutect2, varscan2
- ARCN1 | c.9G>T p.L3= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as COSV50614483; called by mutect2, varscan2
- BTN3A3 | c.687G>T p.L229= | Silent (SNP) | VAF 105/197 reads (53%) | catalogued as COSV55071027; called by muse, mutect2, varscan2
- CDH10 | c.534T>C p.S178= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs1231628581, COSV52571627, COSV52588846; called by muse, mutect2, varscan2
- CELF4 | c.1083C>T p.G361= | Silent (SNP) | VAF 67/86 reads (78%) | catalogued as COSV58447645; called by muse, mutect2, varscan2
- CHIA | c.351G>A p.Q117= (on ENST00000343320; = p.Q9= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 69/218 reads (32%) | catalogued as rs150698600; called by muse, mutect2, varscan2
- CNTRL | c.2532G>A p.Q844= | Silent (SNP) | VAF 81/91 reads (89%) | catalogued as COSV53044097; called by muse, mutect2, varscan2
- CORIN | c.2595T>C p.H865= | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as COSV56687197; called by muse, mutect2, varscan2
- CRLF2 | c.333C>A p.R111= | Silent (SNP) | VAF 92/244 reads (38%) | catalogued as COSV67493444; called by muse, mutect2, varscan2
- CSGALNACT1 | c.408C>G p.G136= | Silent (SNP) | VAF 68/81 reads (84%) | catalogued as COSV59974436, COSV59981769; called by muse, mutect2, varscan2
- CYBB | c.180G>C p.L60= | Silent (SNP) | VAF 65/78 reads (83%) | catalogued as COSV66084864; called by muse, mutect2, varscan2
- DIAPH3 | c.1218C>T p.R406= (on ENST00000400324 / NM_001042517.2; = p.R143= on NM_030932.3) | Silent (SNP) | VAF 56/66 reads (85%) | catalogued as rs1333703096, COSV57365580; called by muse, mutect2, varscan2
- DUSP21 | c.246C>T p.Y82= | Silent (SNP) | VAF 75/87 reads (86%) | catalogued as rs369441582, COSV59133653; called by muse, varscan2
- EFCC1 | c.1624C>T p.L542= | Silent (SNP) | VAF 113/127 reads (89%) | catalogued as rs1489092197, COSV71401776; called by muse, mutect2, varscan2
- ENPP5 | c.627A>T p.S209= | Silent (SNP) | VAF 86/164 reads (52%) | catalogued as COSV57908198; called by muse, mutect2, varscan2
- FAM221B | c.624T>A p.P208= | Silent (SNP) | VAF 71/98 reads (72%) | catalogued as COSV65073783; called by muse, mutect2, varscan2
- FMN2 | c.4629C>T p.L1543= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV60419266; called by muse, mutect2, varscan2
- FRG2C | c.732A>T p.P244= | Silent (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- GJD2 | c.682T>C p.L228= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as rs1379230828, COSV51747306; called by muse, mutect2, varscan2
- H1-2 | c.114C>T p.P38= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as rs780590605, COSV59189848; called by muse, mutect2, varscan2
- H1-5 | c.114G>T p.A38= | Silent (SNP) | VAF 93/166 reads (56%) | catalogued as COSV100137611, COSV58899165; called by muse, mutect2, varscan2
- HMGN2 | c.210A>T p.A70= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV63523236; called by muse, mutect2, varscan2
- HS3ST4 | c.828C>T p.S276= | Silent (SNP) | VAF 87/191 reads (46%) | catalogued as COSV58803812; called by muse, mutect2, varscan2
- IQSEC3 | c.363G>A p.L121= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs782718236, COSV100407650; called by muse, mutect2, varscan2
- ITPRID2 | c.1896G>A p.E632= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV57469890; called by muse, mutect2, varscan2
- KCNQ2 | c.1287C>T p.C429= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1457499206; called by muse, mutect2
- KLHL1 | c.876T>G p.L292= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV64767719; called by muse, mutect2, varscan2
- LNPK | c.453G>A p.P151= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as rs757041047, COSV55822603; called by muse, mutect2, varscan2
- MAP4K4 | c.1059C>T p.R353= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV56325952; called by muse, mutect2, varscan2
- MOCS1 | c.720C>A p.P240= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs548975858, COSV57933907; called by muse, mutect2, varscan2
- MRPL9 | c.795C>G p.P265= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV58617460; called by muse, mutect2, varscan2
- MRTFA | c.558G>A p.K186= | Silent (SNP) | VAF 47/174 reads (27%) | catalogued as rs933197040, COSV62931591; called by muse, mutect2, varscan2
- NANOS3 | c.414G>A p.A138= (on ENST00000397555; = p.A157= on NM_001098622.2) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs557519241, COSV59248465; called by muse, mutect2, varscan2
- NID2 | c.888G>T p.L296= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV53493518; called by muse, mutect2, varscan2
- OR1C1 | c.141G>A p.A47= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs200208817, COSV101376230, COSV68715440, COSV68715730; called by muse, mutect2, varscan2
- OR2L2 | c.105A>T p.L35= | Silent (SNP) | VAF 177/288 reads (61%) | catalogued as COSV63548874; called by muse, mutect2, varscan2
- OR51A4 | c.348C>A p.V116= | Silent (SNP) | VAF 152/281 reads (54%) | catalogued as COSV66749120; called by muse, mutect2, varscan2
- OR5D14 | c.567G>T p.V189= | Silent (SNP) | VAF 169/391 reads (43%) | catalogued as COSV59455582, COSV59459193; called by muse, mutect2, varscan2
- OR5T3 | c.66C>A p.T22= | Silent (SNP) | VAF 66/167 reads (40%) | catalogued as COSV57379560; called by muse, mutect2, varscan2
- PARP1 | c.1494G>A p.K498= | Silent (SNP) | VAF 55/178 reads (31%) | catalogued as COSV64689434; called by muse, mutect2, varscan2
- PDE4A | c.1560C>T p.D520= (on ENST00000380702 / NM_001111307.2; = p.D281= on NM_006202.3) | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV53351393; called by muse, mutect2, varscan2
- PPP1R13B | c.3051T>C p.G1017= | Silent (SNP) | VAF 68/212 reads (32%) | catalogued as COSV52449148; called by muse, mutect2, varscan2
- PRAMEF2 | c.1128C>T p.C376= | Silent (SNP) | VAF 50/220 reads (23%) | catalogued as COSV53572831; called by muse, mutect2, varscan2
- PTCHD3 | c.114G>C p.S38= | Silent (SNP) | VAF 112/264 reads (42%) | catalogued as rs543375628, COSV71256340, COSV71257346; called by muse, mutect2, varscan2
- PTPRB | c.1095G>C p.L365= | Silent (SNP) | VAF 91/200 reads (46%) | catalogued as COSV54234070; called by muse, mutect2, varscan2
- RBM19 | c.258C>A p.P86= | Silent (SNP) | VAF 56/67 reads (84%) | catalogued as COSV55688720; called by muse, mutect2, varscan2
- RSPH10B2 | c.2394C>A p.A798= | Silent (SNP) | VAF 164/262 reads (63%) | called by muse, varscan2
- RUNX2 | c.660A>C p.T220= | Silent (SNP) | VAF 94/247 reads (38%) | catalogued as COSV61839116; called by muse, mutect2, varscan2
- SCN10A | c.636A>C p.S212= | Silent (SNP) | VAF 76/88 reads (86%) | catalogued as COSV71860450; called by muse, mutect2, varscan2
- SCNN1A | c.1521G>A p.S507= | Silent (SNP) | VAF 500/993 reads (50%) | catalogued as rs368914240; called by muse, mutect2, varscan2
- SCTR | c.522C>T p.R174= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV50027004; called by muse, mutect2, varscan2
- SLAMF6 | c.327C>A p.A109= | Silent (SNP) | VAF 144/264 reads (55%) | catalogued as COSV63586504; called by muse, mutect2, varscan2
- SLC4A10 | c.1767A>C p.S589= (on ENST00000446997 / NM_001354461.2; = p.S559= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 98/224 reads (44%) | catalogued as COSV55766382; called by muse, mutect2, varscan2
- SLC9A9 | c.207T>C p.A69= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs112237207, COSV57219597; called by muse, mutect2, varscan2
- SYNE1 | c.7389T>C p.L2463= (on ENST00000367255 / NM_182961.4; = p.L2470= on NM_033071.3) | Silent (SNP) | VAF 85/156 reads (54%) | catalogued as COSV54919247; called by muse, mutect2, varscan2
- TAS1R2 | c.1161C>T p.S387= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs139739080, COSV64743807; called by muse, mutect2
- TMPRSS15 | c.756C>A p.V252= | Silent (SNP) | VAF 140/343 reads (41%) | catalogued as COSV53035550; called by muse, varscan2
- TOX2 | c.888G>T p.L296= (on ENST00000358131 / NM_001098798.2; = p.L245= on NM_032883.3) | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV57883070; called by muse, mutect2, varscan2
- TPTE | c.1485C>T p.Y495= (on ENST00000618007 / NM_199261.4; = p.Y477= on NM_199259.4) | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2
- AP000769.3 | chr11:65501627 ins G | 5'Flank (INS) | VAF 32/160 reads (20%) | catalogued as rs1383618828; called by mutect2, pindel, varscan2
- MARCHF1 | c.-322-85642G>T | Intron (SNP) | VAF 63/88 reads (72%) | catalogued as COSV72275467; called by muse, mutect2, varscan2
- NDUFB9 | c.-1A>G | 5'UTR (SNP) | VAF 71/159 reads (45%) | catalogued as rs556246354, COSV99412989; called by muse, mutect2, varscan2
- PKD1L2 | n.700C>T | RNA (SNP) | VAF 31/73 reads (42%) | catalogued as rs539451747; called by muse, mutect2, varscan2
- TTN | c.10360+5360T>C | Intron (SNP) | VAF 49/94 reads (52%) | catalogued as COSV59910454; called by muse, mutect2, varscan2
- UTS2 | chr1:7853345 G>T | 5'Flank (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2
